Somatic mutation profile of tumor specimen TCGA-D8-A27R-01A (aliquot TCGA-D8-A27R-01A-11D-A16D-09) from TCGA case TCGA-D8-A27R, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 41.4 years (15,122 days).
Specimen TCGA-D8-A27R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9d6cd4f-8397-40ea-af8a-a9d62bf6a29d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27R-10A (Blood Derived Normal), aliquot TCGA-D8-A27R-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef12376a-b35f-4ec2-8354-3329eb9dba55

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, Splice Site 2, Frame Shift Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as rs768107825, COSV62343218; called by muse, mutect2, varscan2
- ATP11A | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99369837; called by muse, mutect2
- AXL | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.88); catalogued as rs751738506, COSV56566509; called by muse, mutect2, varscan2
- BLOC1S6 | c.224C>G p.T75R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55035264, COSV55035355; called by muse, mutect2, varscan2
- CARD6 | c.2497C>A p.P833T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV54565516; called by muse, mutect2, varscan2
- CLCF1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs764602656, COSV56861511; called by muse, mutect2, varscan2
- EPRS1 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.327); catalogued as COSV65097383, COSV65098266; called by muse, mutect2, varscan2
- FBXO33 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV53233929; called by muse, mutect2, varscan2
- KIAA1109 | c.11646+1G>T p.X3882_splice | Splice Site (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52668382; called by muse, mutect2, varscan2
- LARP4B | c.708C>A p.C236* | Nonsense Mutation (SNP) | VAF 51/176 reads (29%) | catalogued as COSV60220914; called by muse, mutect2, varscan2
- MAPK4 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs199714690, COSV68541111; called by muse, mutect2, varscan2
- MOV10L1 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53169674; called by muse, mutect2, varscan2
- MXRA5 | c.6392C>T p.A2131V | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54231204; called by muse, mutect2, varscan2
- MYO16 | c.3158T>C p.F1053S | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697230; called by muse, mutect2
- PCDHAC2 | c.2126T>C p.I709T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV53844971; called by muse, mutect2, varscan2
- PCNX1 | c.2943G>T p.Q981H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV99457064; called by muse, mutect2
- PLCB3 | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54185515, COSV54187433; called by muse, mutect2, varscan2
- PLCXD2 | c.405T>G p.F135L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV101210142, COSV67339593; called by muse, mutect2, varscan2
- TAOK1 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV55590407; called by muse, varscan2
- TLL1 | c.2315-2A>T p.X772_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV50270818; called by muse, mutect2, varscan2
- TRIM32 | c.1080G>C p.K360N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV100530168; called by muse, mutect2
- VIRMA | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99889360; called by muse, mutect2
- ARID1A | c.3459del p.M1154Wfs*7 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- HTR1B | c.804C>G p.T268= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64051344; called by muse, mutect2, varscan2
- INPP1 | c.1110A>G p.G370= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV59415618; called by muse, mutect2, varscan2
- PLXNB3 | c.5289C>T p.A1763= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV62796714; called by muse, mutect2, varscan2
- OR2U1P | n.157C>A | RNA (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
